Somatic mutation profile of tumor specimen ALCH-B40Q-TTP1-A (aliquot ALCH-B40Q-TTP1-A-1-0-D-A80D-36) from ALCHEMIST case ALCH-B40Q, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 53.2 years (19,447 days).
Specimen ALCH-B40Q-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0613ec78-bf63-4bdd-bc18-4ef519d386c9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B40Q-NB1-A (Blood Derived Normal), aliquot ALCH-B40Q-NB1-A-1-0-D-A80D-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7e6ac85f-5cb4-4470-8710-01cbca2bbf7a

The open-access MAF lists 56 somatic variants for this specimen: 42 protein-altering or splice-affecting, 8 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 8, Nonsense Mutation 4, Splice Region 2, 5'UTR 2, Intron 2, Splice Site 1, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 114/476 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.469G>T p.V157F | Missense Mutation (SNP) | VAF 69/168 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912654, CM137621, COSV52667015, COSV52676009, COSV52752314, COSV53205488; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AHNAK2 | c.7339C>T p.P2447S | Missense Mutation (SNP) | VAF 56/210 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.116); catalogued as rs756052629; called by muse, mutect2, varscan2
- ANKRD30BL | c.742G>T p.A248S | Missense Mutation (SNP) | VAF 26/368 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.216); catalogued as rs1428829072, COSV99724260; called by muse, mutect2
- DENND6B | c.228C>G p.I76M | Missense Mutation (SNP) | VAF 69/265 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs768422643; called by muse, mutect2, varscan2
- DOCK4 | c.2771G>A p.R924Q | Missense Mutation (SNP) | VAF 19/137 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.079); catalogued as rs543838556; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.721T>C p.F241L | Missense Mutation (SNP) | VAF 9/220 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as rs1560180797; called by muse, mutect2
- HUWE1 | c.7035G>T p.E2345D | Missense Mutation (SNP) | VAF 16/422 reads (4%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.931); catalogued as COSV53342534; called by muse, mutect2
- METTL7B | c.358G>C p.E120Q | Missense Mutation (SNP) | VAF 24/338 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.893); catalogued as COSV99144851; called by muse, mutect2
- MMGT1 | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs782263638, COSV100018660; called by muse, mutect2
- MYH6 | c.934G>A p.A312T | Missense Mutation (SNP) | VAF 33/300 reads (11%) | SIFT tolerated (0.47); PolyPhen benign (0.228); catalogued as rs748143404; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NHS | c.3952C>T p.Q1318* | Nonsense Mutation (SNP) | VAF 27/491 reads (5%) | catalogued as COSV101196946; called by muse, mutect2
- PCDHA13 | c.1126G>A p.D376N | Missense Mutation (SNP) | VAF 9/194 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV56486128, COSV56538048; called by muse, mutect2
- PIEZO2 | c.6283C>T p.R2095W | Missense Mutation (SNP) | VAF 22/276 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as rs541120113; called by muse, mutect2
- PPARGC1B | c.1981C>T p.R661* | Nonsense Mutation (SNP) | VAF 16/77 reads (21%) | catalogued as COSV100494574; called by muse, mutect2, varscan2
- RAPGEF3 | c.2482G>A p.G828R (on ENST00000389212; = p.G786R on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/273 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV50218977; called by muse, mutect2
- TCIRG1 | c.2267T>C p.M756T | Missense Mutation (SNP) | VAF 68/340 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs760723665; called by muse, mutect2, varscan2
- UACA | c.550C>T p.Q184* | Nonsense Mutation (SNP) | VAF 28/224 reads (13%) | catalogued as COSV100537816; called by muse, mutect2, varscan2
- ZAR1L | c.401C>T p.S134L | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs1281431992, COSV61525390; called by muse, mutect2
- ACKR1 | c.566G>A p.G189D | Missense Mutation (SNP) | VAF 35/166 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ADAM23 | c.970A>G p.N324D | Missense Mutation (SNP) | VAF 12/321 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- ATP6AP2 | c.619C>A p.H207N | Missense Mutation (SNP) | VAF 16/470 reads (3%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2
- C5orf24 | c.181G>T p.E61* | Nonsense Mutation (SNP) | VAF 57/218 reads (26%) | called by muse, mutect2, varscan2
- CAT | c.1577A>C p.N526T | Missense Mutation (SNP) | VAF 12/349 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.26); called by muse, mutect2
- CLHC1 | c.883C>G p.L295V | Missense Mutation (SNP) | VAF 21/194 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- CTNNA3 | c.102T>A p.V34= | Splice Region (SNP) | VAF 8/52 reads (15%) | called by muse, mutect2, varscan2
- DNAH3 | c.11539A>T p.I3847F | Missense Mutation (SNP) | VAF 24/175 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- HELZ2 | c.6894C>G p.I2298M (on ENST00000467148 / NM_001037335.2; = p.I1729M on NM_033405.3) | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- KRTAP10-2 | c.293C>T p.A98V | Missense Mutation (SNP) | VAF 16/652 reads (2%) | SIFT tolerated (0.23); PolyPhen benign (0.061); called by muse, mutect2
- LEFTY1 | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 12/322 reads (4%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.874); called by muse, mutect2
- MATN2 | c.176T>C p.V59A | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- MROH8 | c.1583G>T p.R528M | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- NBEA | c.6636A>G p.I2212M | Missense Mutation (SNP) | VAF 39/146 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- PEX13 | c.92+8T>A | Splice Region (SNP) | VAF 9/112 reads (8%) | called by muse, mutect2
- POLR1B | c.2528G>A p.S843N | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.84); PolyPhen benign (0.009); called by muse, mutect2
- RBM48 | c.518A>T p.H173L | Missense Mutation (SNP) | VAF 40/149 reads (27%) | SIFT tolerated (0.6); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- RELA | c.35-1G>C p.X12_splice | Splice Site (SNP) | VAF 5/91 reads (5%) | called by muse, mutect2
- RLIM | c.1520G>A p.G507D | Missense Mutation (SNP) | VAF 14/135 reads (10%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.505); called by muse, mutect2, varscan2
- SLC12A5 | c.607G>A p.V203M (on ENST00000454036 / NM_001134771.2; = p.V180M on NM_020708.5) | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLC5A3 | c.1664A>C p.K555T | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC8A1 | c.2633T>A p.V878D | Missense Mutation (SNP) | VAF 10/192 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SYNE1 | c.20557T>G p.S6853A (on ENST00000367255 / NM_182961.4; = p.S6782A on NM_033071.3) | Missense Mutation (SNP) | VAF 63/365 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- CLCN4 | c.1272G>C p.R424= | Silent (SNP) | VAF 40/220 reads (18%) | catalogued as COSV66465039; called by muse, mutect2, varscan2
- EP300 | c.1275T>C p.N425= | Silent (SNP) | VAF 64/215 reads (30%) | called by muse, mutect2, varscan2
- ERBB4 | c.480C>T p.T160= | Silent (SNP) | VAF 29/278 reads (10%) | catalogued as rs745409267; called by muse, mutect2, varscan2
- HOXB9 | c.384G>C p.L128= | Silent (SNP) | VAF 32/255 reads (13%) | called by muse, mutect2, varscan2
- SATL1 | c.735T>C p.S245= (on ENST00000395409; = p.S432= on NM_001012980.2) | Silent (SNP) | VAF 12/256 reads (5%) | called by muse, mutect2
- SERINC2 | c.21C>G p.A7= | Silent (SNP) | VAF 8/118 reads (7%) | catalogued as COSV65490615; called by muse, mutect2
- SERPINE3 | c.801C>T p.D267= | Silent (SNP) | VAF 16/301 reads (5%) | called by muse, mutect2
- SGK2 | c.84C>T p.C28= | Silent (SNP) | VAF 34/149 reads (23%) | called by muse, mutect2, varscan2
- CHRM2 | c.-36T>G | 5'UTR (SNP) | VAF 20/129 reads (16%) | called by muse, mutect2, varscan2
- CIAO3 | c.67-309del | Intron (DEL) | VAF 27/127 reads (21%) | catalogued as COSV99285310; called by mutect2, pindel, varscan2
- DYNC1H1 | c.7614+35T>A | Intron (SNP) | VAF 56/447 reads (13%) | called by muse, mutect2, varscan2
- GPX4 | c.*65A>T | 3'UTR (SNP) | VAF 9/33 reads (27%) | called by muse, mutect2, varscan2
- NOL4L-DT | n.155T>A | RNA (SNP) | VAF 8/216 reads (4%) | called by muse, mutect2
- VEZT | c.-18G>A | 5'UTR (SNP) | VAF 14/190 reads (7%) | catalogued as COSV99704008; called by muse, mutect2
